Somatic mutation profile of tumor specimen C3N-02631-02 (aliquot CPT0181960007) from CPTAC case C3N-02631, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 77.0 years (28,135 days).
Specimen C3N-02631-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b844134-3f2e-4bd5-915f-cf7f140c1549.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02631-31 (Blood Derived Normal), aliquot CPT0182010002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21fdad6d-56df-41f3-90ce-da0c5d08c992

The open-access MAF lists 75 somatic variants for this specimen: 59 protein-altering or splice-affecting, 12 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 12, Nonsense Mutation 5, Intron 2, RNA 2, In Frame Del 1, Splice Region 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 166/268 reads (62%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- TP53 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 332/443 reads (75%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACTR6 | c.379+3G>A | Splice Region (SNP) | VAF 53/123 reads (43%) | catalogued as rs948595715; called by muse, mutect2, varscan2
- C4orf45 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV101465149; called by muse, mutect2, varscan2
- CAPN8 | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 22/355 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); catalogued as rs887860724; called by muse, mutect2
- CNTN1 | c.2932G>A p.A978T | Missense Mutation (SNP) | VAF 186/426 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.088); catalogued as rs773622747, COSV100751996; called by muse, mutect2, varscan2
- CNTNAP2 | c.2744G>T p.R915L | Missense Mutation (SNP) | VAF 153/383 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.102); catalogued as rs369919189, COSV62155012; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP27B1 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 193/535 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs577501884; called by muse, mutect2, varscan2
- ENTPD3 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 117/260 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs780128361; called by muse, mutect2, varscan2
- FSIP2 | c.6026G>C p.R2009T | Missense Mutation (SNP) | VAF 88/177 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV104420842; called by muse, mutect2, varscan2
- GABRE | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.594); catalogued as rs372761627, COSV64821907; called by muse, mutect2, varscan2
- GPR37L1 | c.691G>A p.V231M | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as rs775034100; called by muse, mutect2, varscan2
- INF2 | c.2893G>A p.G965R | Missense Mutation (SNP) | VAF 252/318 reads (79%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs370783381; called by muse, mutect2, varscan2
- IRS4 | c.3674C>T p.P1225L | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.013); catalogued as rs752900509, COSV100929508; called by muse, mutect2, varscan2
- KMT2B | c.6739G>A p.G2247R | Missense Mutation (SNP) | VAF 65/101 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs376011791; called by muse, mutect2, varscan2
- LAMA2 | c.7781G>A p.R2594H | Missense Mutation (SNP) | VAF 217/512 reads (42%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.952); catalogued as rs368311592, COSV101370725; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTSS2 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 300/436 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1260946304, COSV58698976; called by muse, mutect2, varscan2
- NBPF11 | c.1445G>T p.C482F | Missense Mutation (SNP) | VAF 102/649 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); catalogued as rs1237284840; called by muse, varscan2
- OLFM1 | c.857C>T p.T286M (on ENST00000371793 / NM_001282611.2; = p.T268M on NM_014279.5) | Missense Mutation (SNP) | VAF 92/147 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs372599021; called by muse, mutect2, varscan2
- PRKCB | c.430G>T p.V144L | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.426); catalogued as COSV57807753; called by muse, mutect2
- PSD2 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 252/528 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs749486846; called by muse, mutect2, varscan2
- QRICH2 | c.4573C>T p.R1525C | Missense Mutation (SNP) | VAF 272/351 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs369758266; called by muse, mutect2, varscan2
- RAD21 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 71/160 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.138); catalogued as rs1425483905; called by muse, mutect2, varscan2
- SHROOM2 | c.1030G>T p.A344S | Missense Mutation (SNP) | VAF 38/457 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.112); catalogued as COSV66606705; called by muse, mutect2
- SORCS1 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 105/259 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.082); catalogued as rs546084462, COSV53840434; called by muse, mutect2, varscan2
- ANKRD63 | c.609C>A p.S203R | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.05); called by muse, mutect2, varscan2
- BACE2 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 117/309 reads (38%) | called by muse, mutect2, varscan2
- BRWD3 | c.5093G>C p.G1698A | Missense Mutation (SNP) | VAF 11/256 reads (4%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.096); called by muse, mutect2
- CASZ1 | c.4897C>T p.Q1633* | Nonsense Mutation (SNP) | VAF 14/167 reads (8%) | called by muse, mutect2
- CBLL2 | c.1085T>A p.L362H | Missense Mutation (SNP) | VAF 22/369 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.417); called by muse, mutect2
- CERK | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 162/325 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHD4 | c.3290A>G p.D1097G (on ENST00000357008 / NM_001363606.2; = p.D1110G on NM_001273.5) | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- COL4A1 | c.1037G>T p.R346M | Missense Mutation (SNP) | VAF 147/381 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- DENND5A | c.3608C>T p.T1203I | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- GALM | c.152G>A p.R51K | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GNPDA1 | c.88G>T p.G30W | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- H2BC13 | c.125T>A p.V42E | Missense Mutation (SNP) | VAF 388/899 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- INPP5B | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 19/296 reads (6%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.36); called by muse, mutect2
- KCND1 | c.1121+1G>C p.X374_splice | Splice Site (SNP) | VAF 86/172 reads (50%) | called by mutect2, varscan2
- LCE1B | c.235C>A p.H79N | Missense Mutation (SNP) | VAF 99/379 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- LEP | c.263G>T p.S88I | Missense Mutation (SNP) | VAF 250/540 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- MTR | c.3067C>T p.Q1023* | Nonsense Mutation (SNP) | VAF 165/510 reads (32%) | called by muse, mutect2, varscan2
- OR5L2 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 97/248 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PDCD11 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 13/197 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); called by muse, mutect2
- PDE10A | c.2066C>T p.A689V | Missense Mutation (SNP) | VAF 130/328 reads (40%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRCC | c.154C>G p.P52A | Missense Mutation (SNP) | VAF 142/533 reads (27%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRND | c.202A>G p.I68V | Missense Mutation (SNP) | VAF 306/626 reads (49%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- SENP6 | c.3021_3023del p.R1007del | In Frame Del (DEL) | VAF 78/186 reads (42%) | called by pindel, varscan2
- SLC22A1 | c.503A>T p.Y168F | Missense Mutation (SNP) | VAF 21/322 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2
- SPEN | c.5589G>T p.Q1863H | Missense Mutation (SNP) | VAF 104/270 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SUPT20HL1 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 125/293 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- TECPR2 | c.3273_3292del p.S1092Rfs*3 | Frame Shift Del (DEL) | VAF 141/222 reads (64%) | called by mutect2, pindel, varscan2
- TEX13B | c.917C>A p.A306D | Missense Mutation (SNP) | VAF 65/196 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- TNS3 | c.4328A>G p.K1443R | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.141); called by muse, mutect2
- TRAJ6 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 72/108 reads (67%) | called by muse, mutect2, varscan2
- TRBV23-1 | c.254C>A p.S85* | Nonsense Mutation (SNP) | VAF 158/281 reads (56%) | called by muse, mutect2, varscan2
- TRBV4-2 | c.283C>T p.L95F | Missense Mutation (SNP) | VAF 19/328 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRPM8 | c.875A>C p.D292A | Missense Mutation (SNP) | VAF 115/278 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- YY1AP1 | c.2202C>A p.C734* (on ENST00000295566 / NM_139118.2; = p.C677* on NM_018253.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 243/1015 reads (24%) | called by muse, mutect2, varscan2
- DLL1 | c.1941C>G p.L647= | Silent (SNP) | VAF 144/339 reads (42%) | called by muse, mutect2, varscan2
- EN1 | c.345C>T p.F115= | Silent (SNP) | VAF 229/522 reads (44%) | called by muse, mutect2, varscan2
- FRMPD4 | c.2241C>T p.D747= | Silent (SNP) | VAF 146/322 reads (45%) | catalogued as rs769972556, COSV66216986; called by muse, mutect2, varscan2
- GPN2 | c.687C>T p.I229= | Silent (SNP) | VAF 45/186 reads (24%) | catalogued as rs755739809; called by muse, mutect2, varscan2
- KIRREL2 | c.1161C>T p.G387= | Silent (SNP) | VAF 30/79 reads (38%) | called by muse, mutect2, varscan2
- MXRA5 | c.7320C>G p.P2440= | Silent (SNP) | VAF 24/266 reads (9%) | called by muse, mutect2
- PLP1 | c.18C>T p.C6= | Silent (SNP) | VAF 70/230 reads (30%) | catalogued as rs151116667; called by muse, mutect2, varscan2
- PON3 | c.36C>T p.V12= | Silent (SNP) | VAF 223/510 reads (44%) | catalogued as rs930141482; called by muse, mutect2, varscan2
- RFX1 | c.2004G>C p.V668= | Silent (SNP) | VAF 26/450 reads (6%) | catalogued as rs1057277639; called by muse, mutect2
- SEC61A1 | c.738C>T p.I246= | Silent (SNP) | VAF 162/416 reads (39%) | catalogued as COSV99684862; called by muse, mutect2, varscan2
- VPS39 | c.2529G>A p.K843= (on ENST00000348544 / NM_001301138.2; = p.K832= on NM_015289.5) | Silent (SNP) | VAF 111/316 reads (35%) | catalogued as rs1190046935; called by muse, mutect2, varscan2
- ZBTB14 | c.351C>A p.I117= | Silent (SNP) | VAF 54/132 reads (41%) | called by muse, mutect2, varscan2
- ID1 | c.427-13_427-11del | Intron (DEL) | VAF 160/446 reads (36%) | catalogued as rs1398378560; called by mutect2, pindel, varscan2
- PASK | c.197-20C>T | Intron (SNP) | VAF 97/229 reads (42%) | catalogued as rs777338405, COSV52153401; called by muse, mutect2, varscan2
- TPRX2P | n.533A>G | RNA (SNP) | VAF 6/145 reads (4%) | called by muse, mutect2
- ZNF767P | n.330C>T | RNA (SNP) | VAF 243/613 reads (40%) | catalogued as rs751211622; called by muse, mutect2, varscan2
